Gene-level copy-number profile of tumor specimen TCGA-CR-6478-01A from TCGA case TCGA-CR-6478, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; Tumor grade: G3; Age at diagnosis: 66.4 years (24,244 days).
Specimen TCGA-CR-6478-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.4c5573f8-a5e8-474f-b581-1998bb70f3bb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CR-6478-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4f726e38-5351-4fb1-8049-0b5973d72fec

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 211; copy number 1: 17,618; copy number 2: 38,097; copy number 3: 2,115; copy number 4: 673; copy number 5: 346; copy number 6: 276; copy number 7: 108; copy number 8: 30; copy number 9: 160; copy number 10: 39; copy number 11: 90; copy number 13: 18; copy number 14: 18; copy number 18: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CR-6478-01A-11D-1869-01): tumor purity 0.28, ploidy 3.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 211 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:54,808,210–63,571,617, 139 genes (broad region; genes not listed).
- chr6:120,462,511–120,706,789, 2 genes (within-gene range 0–2): AL096854.1, RNU6-214P.
- chr8:3,700,492–4,329,027, 2 genes: RNA5SP251, AC027251.1.
- chr10:34,488,583–34,488,878, 1 gene: ELOBP4.
- chr13:26,557,683–26,688,948, 2 genes (within-gene range 0–1): WASF3, WASF3-AS1.
- chr18:41,955,234–42,115,538, 4 genes (within-gene range 0–2): PIK3C3, AC087683.2, AC087683.1, AC087683.3.
- chr19:29,698,886–33,064,888, 61 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,104 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:83,594,956–83,657,842, 2 genes, copy number 10: RPL37P10, RNU6-1312P.
- chr2:96,010,551–98,936,259, 83 genes, copy number 6–9 (within-gene range 1–9) (broad region; genes not listed).
- chr2:99,284,238–99,490,035, 5 genes, copy number 10: LYG1, TXNDC9, EIF5B, REV1, AC018690.1.
- chr3:189,829,922–189,830,009, 1 gene, copy number 6: MIR944.
- chr3:189,969,030–189,969,861, 1 gene, copy number 6: MTAPP2.
- chr6:28,378,955–29,510,558, 62 genes, copy number 5–13 (broad region; genes not listed).
- chr6:30,414,715–31,083,109, 48 genes, copy number 5–18: MICC, AL662873.1, TMPOP1, SUCLA2P1, RANP1, HLA-E, LINC02569, GNL1, PRR3, ABCF1, MIR877, PPP1R10, MRPS18B, ATAT1, PTMAP1, C6orf136, DHX16, PPP1R18, NRM, RPL7P4, MDC1, MDC1-AS1, TUBB, AL662797.1, FLOT1, Y_RNA, IER3-AS1, IER3, HCG20, RN7SL353P, LINC00243, LINC02570, RN7SKP186, DDR1-DT, DDR1, MIR4640, GTF2H4, AL669830.1, VARS2, SFTA2, Y_RNA, MUCL3, HCG21, NAPGP2, MUC21, MUC22, HCG22, RNU6-1133P.
- chr6:31,462,728–32,896,490, 135 genes, copy number 5 (broad region; genes not listed).
- chr6:63,275,951–65,707,226, 19 genes, copy number 5 (within-gene range 3–5): LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1.
- chr6:67,456,346–68,635,161, 15 genes, copy number 8–10: AL365503.1, RNA5SP208, RNU6-280P, Y_RNA, AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1, LINC02549, AL606923.2, AL606923.1, AL391807.1.
- chr7:81,946,444–82,443,777, 1 gene, copy number 5 (within-gene range 2–7): CACNA2D1.
- chr7:82,589,848–89,496,918, 60 genes, copy number 5–6: MTHFD2P5, AC004006.1, PCLO, RNA5SP235, AC079799.1, SEMA3E, AC079799.2, AC079987.1, RAD23BP2, SEMA3A, RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972, AC092013.1, SOCS5P1, GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4, ABCB1, HNRNPA1P9, RUNDC3B, SLC25A40, DBF4, ADAM22, SRI, SRI-AS1, AC003991.1, STEAP4, AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1, ZNF804B, TEX47, AC002383.1.
- chr7:101,362,875–101,559,024, 1 gene, copy number 6 (within-gene range 4–6): COL26A1.
- chr7:101,562,779–104,208,047, 70 genes, copy number 6–9 (broad region; genes not listed).
- chr9:3,218,297–19,049,358, 187 genes, copy number 5–14 (within-gene range 3–14) (broad region; genes not listed).
- chr10:43,523,256–44,515,421, 29 genes, copy number 6–8: AL450326.2, ZNF239, AL450326.3, CAP1P2, ZNF485, ZNF32-AS3, AL645634.2, RPL21P88, ZNF32, ZNF32-AS1, ZNF32-AS2, AL645634.1, SPRING1P1, UQCRHP3, ELOCP30, LINC02658, LINC00840, HNRNPA3P1, LINC02659, LINC00841, AL139237.1, AL137026.2, AL137026.1, LINC02881, AL137026.3, CXCL12, RPL9P21, AL356157.2, AL356157.3.
- chr11:40,114,203–41,459,773, 1 gene, copy number 9 (within-gene range 1–9): LRRC4C.
- chr11:41,122,907–45,286,341, 64 genes, copy number 6–9 (broad region; genes not listed).
- chr11:67,974,286–70,436,584, 73 genes, copy number 9 (broad region; genes not listed).
- chr11:70,477,277–70,706,068, 6 genes, copy number 9: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1.
- chr11:71,563,389–72,080,693, 31 genes, copy number 7 (within-gene range 1–7): AP000867.5, KRTAP5-10, AP000867.1, KRTAP5-11, KRTAP5-14P, OR7E87P, UNC93B6, OR7E4P, AP000867.3, AP000867.4, RPS3AP41, ALG1L9P, SNRPCP14, AP003498.1, ENPP7P8, AP003498.2, FAM86C1P, ALG1L9P, ZNF705E, DEFB108B, RNA5SP342, DEFB130C, AP002495.1, DEFB131B, OR7E128P, OR7E126P, RNF121, AP002490.2, IL18BP, NUMA1, AP002490.1.
- chr12:65,134,688–67,069,162, 34 genes, copy number 6–11 (within-gene range 4–11): APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4.
- chr12:68,610,855–68,671,901, 1 gene, copy number 9 (within-gene range 4–9): RAP1B.
- chr12:68,642,519–70,920,738, 51 genes, copy number 5–9: ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA.
- chr18:47,390–1,408,344, 43 genes, copy number 5: TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2.
- chr20:31,257,664–32,003,387, 40 genes, copy number 5 (within-gene range 3–5): DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2.
- chr20:43,894,720–45,138,976, 41 genes, copy number 7–10: LINC01728, TOX2, RN7SL443P, JPH2, AL035447.1, OSER1, OSER1-DT, GDAP1L1, FITM2, R3HDML, Y_RNA, AL117382.1, HNF4A, HNF4A-AS1, AL117382.2, MIR3646, LINC01620, RPL37AP1, TTPAL, SERINC3, PKIG, ADA, LINC01260, AL139352.1, KCNK15-AS1, CCN5, KCNK15, AL118522.1, RIMS4, PGBD4P2, AL008725.1, YWHAB, PABPC1L, TOMM34, STK4-AS1, STK4, Y_RNA, KCNS1, WFDC5, WFDC12, AL049767.1.

Autosomal genes at a single copy (total copy number 1): 15,555. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
